Somatic mutation profile of tumor specimen MP2PRT-PAVNHF-TMP1-A (aliquot MP2PRT-PAVNHF-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAVNHF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.6 years (2,764 days).
Specimen MP2PRT-PAVNHF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f45497af-9934-40f8-801a-2e417ebfdd55.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVNHF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVNHF-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8a93410-35cb-4364-9233-f3b8cfad1a8c

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 4, 3'Flank 1, Intron 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD4 | c.421del p.I141Sfs*58 | Frame Shift Del (DEL) | VAF 120/583 reads (21%) | catalogued as COSV53530763; called by mutect2, pindel, varscan2
- ACTR6 | c.133A>G p.I45V | Missense Mutation (SNP) | VAF 75/219 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.393); catalogued as rs745605106; called by muse, mutect2, varscan2
- GTF3C3 | c.267G>A p.M89I | Missense Mutation (SNP) | VAF 186/454 reads (41%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.838); catalogued as COSV99826725; called by muse, mutect2, varscan2
- SLC25A39 | c.1041C>A p.F347L (on ENST00000377095 / NM_001143780.3; = p.F339L on NM_016016.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 128/306 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs779362695; called by muse, mutect2, varscan2
- ZNF541 | c.49C>T p.H17Y | Missense Mutation (SNP) | VAF 171/404 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV58462753; called by muse, mutect2, varscan2
- COP1 | c.1585T>A p.L529M | Missense Mutation (SNP) | VAF 120/334 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- DZIP1 | c.254A>G p.D85G | Missense Mutation (SNP) | VAF 269/664 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HOXD10 | c.688A>G p.S230G | Missense Mutation (SNP) | VAF 161/426 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- NEFH | c.1147C>T p.R383* | Nonsense Mutation (SNP) | VAF 152/394 reads (39%) | called by muse, mutect2, varscan2
- UXS1 | c.658G>T p.G220C | Missense Mutation (SNP) | VAF 96/272 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS9 | c.5460G>A p.T1820= | Silent (SNP) | VAF 168/422 reads (40%) | catalogued as rs531081510, COSV55784085; called by muse, mutect2, varscan2
- CSMD3 | c.2196T>A p.V732= (on ENST00000297405 / NM_001363185.1; = p.V628= on NM_052900.3) | Silent (SNP) | VAF 59/290 reads (20%) | called by muse, mutect2, varscan2
- DOCK5 | c.1479T>C p.I493= | Silent (SNP) | VAF 88/317 reads (28%) | called by muse, mutect2, varscan2
- OR11H1 | c.603G>C p.L201= | Silent (SNP) | VAF 30/604 reads (5%) | called by muse, mutect2
- ERBIN | c.3634-3225G>A | Intron (SNP) | VAF 130/347 reads (37%) | called by muse, mutect2, varscan2
- IGKV1D-16 | chr2:90100738 ins CCCC | 3'Flank (INS) | VAF 59/117 reads (50%) | called by mutect2, varscan2
